Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LP, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LP-01A (Primary Tumor).

Procedure: Right adrenalectomy

Gross description: tumor is 198g; measuring 8.5 x 7.5 x 6cm.

Diagnosis: tumor has oxyphilic cells. Weiss score = 5, consistent with carcinoma.
Based on paper from Bisceglia et al, this tumor is classified as tumor with
malignancy potential. No lymph node metastases (+0/30). 1.4 hyperplastic nodule
on segment V of liver. s/p cholecystectomy (no change in histology of gallbladder).

ICD-O-3

Carcinoma, adrenal cortical
8370/3

Site: (R) Adrenal Gland Cortex
C74.0

Jan 2/6/13

Site Discrepancy		
Primary Tumor History		
Reviewed Initials	1/16/13	

Source: NCI Genomic Data Commons file 28201316-1ebf-4650-9654-88dadc58e147 (TCGA-OR-A5LP.FCD998EA-2EEA-4A94-80A6-D87F962BBC87.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).